Somatic mutation profile of tumor specimen 0D9JNR from CCDI case PBBIHJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.3 years (6,318 days).
Specimen 0D9JNR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f0de834-fc85-41b4-82a8-eacf4aa0f2e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9JNS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0194b0a9-ba77-42ed-901e-b7f028328393

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT9 | c.1335G>A p.M445I | Missense Mutation (SNP) | VAF 26/934 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- ZNF10 | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 156/547 reads (29%) | called by muse, mutect2, varscan2
- ARHGAP12 | c.1242A>G p.P414= | Silent (SNP) | VAF 28/562 reads (5%) | called by muse, mutect2
